Somatic mutation profile of tumor specimen TCGA-AA-3856-01A (aliquot TCGA-AA-3856-01A-01W-0900-09) from TCGA case TCGA-AA-3856, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.3 years (21,670 days).
Specimen TCGA-AA-3856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 061d5ea3-4981-4ac2-be0e-16db76157644.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3856-10A (Blood Derived Normal), aliquot TCGA-AA-3856-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2a32290-b13b-4b35-82a2-d1340dbd853f

The open-access MAF lists 67 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 74/107 reads (69%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC004922.1 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1436553465, COSV53556297; called by muse, mutect2, varscan2
- ACSL4 | c.1515C>T p.G505= (on ENST00000340800 / NM_022977.2; = p.G464= on NM_004458.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 108/264 reads (41%) | catalogued as rs779703364, COSV61614853; called by muse, mutect2, varscan2
- ADGRL2 | c.2477A>G p.N826S (on ENST00000370717 / NM_001366005.1; = p.N813S on NM_012302.4) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.773); catalogued as rs776616316, COSV54673186, COSV99590431; called by muse, mutect2, varscan2
- AICDA | c.213C>A p.D71E | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as COSV57564897; called by muse, mutect2, varscan2
- ASIC2 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs147403420; called by muse, mutect2, varscan2
- ATP6AP2 | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV65797912; called by muse, mutect2, varscan2
- C8A | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143726641, COSV63484861; called by muse, mutect2, varscan2
- CAMTA1 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.318); catalogued as COSV57907557; called by muse, mutect2, varscan2
- CCDC103 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53651483; called by muse, mutect2, varscan2
- COL12A1 | c.1588A>T p.I530L | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV59398713; called by muse, mutect2, varscan2
- COL4A4 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929684384, COSV100306072; called by muse, mutect2, varscan2
- CST9 | c.316T>C p.F106L | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.291); catalogued as COSV65402720; called by muse, mutect2, varscan2
- CYP20A1 | c.1175A>C p.E392A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV61909736; called by muse, mutect2
- DCUN1D1 | c.571A>C p.K191Q | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV53044988; called by muse, mutect2, varscan2
- G6PC3 | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as rs745582203, CM118963, COSV52242853; called by muse, mutect2, varscan2
- GABRA4 | c.1625T>G p.L542* | Nonsense Mutation (SNP) | VAF 78/133 reads (59%) | catalogued as COSV51930159; called by muse, mutect2, varscan2
- GNB4 | c.236T>G p.L79* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as COSV51710128; called by muse, mutect2, varscan2
- GPR50 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV54440123; called by muse, mutect2, varscan2
- GPR6 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV51571261; called by muse, mutect2, varscan2
- HNF4A | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1032055611, CM125274, COSV57379967; called by muse, mutect2
- INHBA | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV99637035; called by muse, mutect2
- KBTBD3 | c.1435T>C p.Y479H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73241485; called by muse, mutect2, varscan2
- KCND3 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56176760; called by muse, mutect2, varscan2
- KRTAP19-6 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.728); catalogued as COSV61844113, COSV61844456; called by muse, mutect2, varscan2
- LENG8 | c.2230A>G p.M744V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs1261453412, COSV100417804; called by muse, mutect2
- LOXL2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as rs745851452, COSV66692023; called by muse, mutect2
- MAP3K12 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1351746929, COSV57233708; called by muse, mutect2, varscan2
- MYH14 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775122875, COSV51821927; called by muse, mutect2, varscan2
- NALCN | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs756048159, COSV51943813; called by muse, mutect2, varscan2
- NHEJ1 | c.628T>G p.F210V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59430568; called by muse, mutect2, varscan2
- NTRK1 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761967383, COSV62323124; called by muse, mutect2, varscan2
- OCLN | c.1038-1G>A p.X346_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100783751; called by mutect2, varscan2
- PCDH18 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as rs140746327; called by muse, mutect2, varscan2
- PCDHB14 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 56/79 reads (71%) | catalogued as COSV53386784, COSV53389653; called by muse, mutect2, varscan2
- PCOLCE2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); catalogued as rs375192412; called by muse, mutect2, varscan2
- PLXDC2 | c.1212G>T p.R404S | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs760841125, COSV65905326; called by muse, mutect2, varscan2
- RALYL | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs749865840, COSV72819608; called by muse, mutect2, varscan2
- ROPN1B | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV52542604; called by muse, mutect2
- SDK1 | c.3649C>T p.R1217C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs758661396, COSV67357298, COSV67362495; called by muse, mutect2, varscan2
- SEC11C | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55311703; called by muse, mutect2, varscan2
- SLC44A5 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs202241076, COSV63761623; called by muse, mutect2, varscan2
- SPECC1 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs765479679, COSV54960345; called by mutect2, varscan2
- STK38 | c.1069A>G p.I357V | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV57709334; called by muse, mutect2, varscan2
- TP53 | c.965del p.P322Hfs*23 | Frame Shift Del (DEL) | VAF 48/107 reads (45%) | catalogued as COSV52729459, COSV52826955; called by mutect2, pindel, varscan2
- WDR41 | c.1101dup p.N368* | Frame Shift Ins (INS) | VAF 25/165 reads (15%) | catalogued as rs748110033; called by mutect2, varscan2
- WDR75 | c.1715G>A p.S572N | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV59106005; called by muse, mutect2, varscan2
- ZNF264 | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54041188, COSV54042354; called by muse, mutect2, varscan2
- ZNF528 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs780654618, COSV64619796; called by muse, mutect2, varscan2
- BLID | c.41dup p.F15Lfs*2 | Frame Shift Ins (INS) | VAF 74/220 reads (34%) | called by mutect2, pindel, varscan2
- DDX58 | c.69_72del p.Y24Sfs*2 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2
- PIBF1 | c.1954A>C p.K652Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, varscan2
- PIBF1 | c.1962_1964+2del | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by pindel, varscan2
- APOB | c.1332G>A p.A444= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs747757675, COSV51940449; called by muse, mutect2, varscan2
- ARHGAP33 | c.264C>T p.T88= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV50127622; called by muse, mutect2
- DAPK1 | c.1500C>T p.A500= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs765826018, COSV63788610; called by muse, mutect2, varscan2
- ESPL1 | c.4833G>A p.R1611= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs779415897, COSV57760232; called by muse, mutect2, varscan2
- FAM47A | c.585G>A p.P195= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs769496249, COSV60497724; called by muse, mutect2, varscan2
- GOLGA2 | c.2835C>T p.N945= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs1267496210, COSV57852791; called by muse, mutect2, varscan2
- HOXB4 | c.684C>T p.I228= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1303109042, COSV100203672; called by muse, mutect2
- LRRC8A | c.1269C>T p.N423= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs750593208, COSV52186895; called by muse, mutect2, varscan2
- OR8G5 | c.126C>T p.N42= | Silent (SNP) | VAF 30/240 reads (13%) | catalogued as COSV100422188; called by muse, mutect2, varscan2
- PDE8A | c.1149G>A p.R383= | Silent (SNP) | VAF 70/247 reads (28%) | catalogued as COSV59638004; called by muse, mutect2, varscan2
- PLEKHA7 | c.648C>T p.I216= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV63047547; called by muse, mutect2, varscan2
- RGS13 | c.312G>C p.S104= | Silent (SNP) | VAF 51/111 reads (46%) | catalogued as rs149936703, COSV67346281; called by muse, mutect2, varscan2
- SEMA6C | c.990C>T p.A330= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs755089884, COSV59004514; called by muse, mutect2, varscan2
- DDC | c.-1C>G | 5'UTR (SNP) | VAF 37/100 reads (37%) | catalogued as COSV100779094; called by muse, mutect2, varscan2
